Somatic mutation profile of tumor specimen TCGA-FX-A3NK-01A (aliquot TCGA-FX-A3NK-01A-11D-A21Q-09) from TCGA case TCGA-FX-A3NK, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Stomach, NOS; Age at diagnosis: 53.5 years (19,533 days).
Specimen TCGA-FX-A3NK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d45e300-92a6-4403-9627-22fabbcb2988.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FX-A3NK-10A (Blood Derived Normal), aliquot TCGA-FX-A3NK-10A-01D-A21Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e472d7be-70a9-4c7c-8ef5-517ae5532e72

The open-access MAF lists 27 somatic variants for this specimen: 20 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 5, Intron 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- USH1C | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs776511246, COSV50018869; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BIRC3 | c.101C>G p.S34C | Missense Mutation (SNP) | VAF 9/210 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54820458; called by muse, mutect2
- C9orf43 | c.230C>T p.T77I | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as COSV99928541; called by muse, mutect2, varscan2
- CACNA1A | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.644); catalogued as rs1391039223, COSV100803025; called by muse, mutect2, varscan2
- CLEC4F | c.1331G>A p.R444H | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs782797954, COSV55478693, COSV55479364; called by muse, mutect2
- DPF2 | c.599C>G p.S200C | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as COSV99361858; called by muse, mutect2, varscan2
- FAT1 | c.10795C>G p.L3599V | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.038); catalogued as COSV101499575; called by mutect2, varscan2
- FAT1 | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71676745; called by muse, mutect2, varscan2
- NAV1 | c.5443C>T p.P1815S | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.92); catalogued as COSV99819464; called by muse, mutect2, varscan2
- NAV3 | c.2503G>A p.D835N | Missense Mutation (SNP) | VAF 78/2762 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as COSV99894289; called by muse, mutect2
- NRXN1 | c.1577A>C p.H526P | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV100456423, COSV58446514; called by muse, mutect2, varscan2
- OR2H1 | c.493C>G p.P165A | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101009900; called by muse, mutect2, varscan2
- PCDHA11 | c.232A>G p.N78D | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.229); catalogued as COSV100253137; called by muse, mutect2
- PSMD9 | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99945753; called by muse, mutect2, varscan2
- RAD23B | c.1062T>G p.S354R | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.402); catalogued as COSV100787761; called by muse, mutect2
- SPTBN4 | c.5494G>A p.A1832T | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.983); catalogued as rs764760284, COSV100151776; called by muse, mutect2, varscan2
- TRHDE | c.1268C>A p.P423H | Missense Mutation (SNP) | VAF 255/565 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99671982; called by muse, mutect2, varscan2
- VPS13C | c.5246A>G p.Q1749R (on ENST00000644861 / NM_020821.3; = p.Q1706R on NM_017684.5) | Missense Mutation (SNP) | VAF 27/39 reads (69%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as COSV99829746; called by muse, mutect2, varscan2
- ZSCAN30 | c.1412G>C p.C471S | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99735084; called by muse, mutect2, varscan2
- ZNF492 | c.634del p.T213Lfs*5 | Frame Shift Del (DEL) | VAF 15/59 reads (25%) | called by mutect2, pindel, varscan2
- CLASP1 | c.261G>A p.A87= | Silent (SNP) | VAF 30/78 reads (38%) | catalogued as rs1206666460, COSV99756628; called by muse, mutect2, varscan2
- CORIN | c.2469C>T p.P823= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV99904219; called by muse, mutect2, varscan2
- L3MBTL4 | c.63C>T p.D21= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs759827055, COSV53115083; called by muse, mutect2, varscan2
- OR4C15 | c.648T>C p.T216= (on ENST00000314644; = p.T162= on NM_001001920.2) | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs1400441219, COSV100115968; called by muse, mutect2, varscan2
- SCGN | c.714C>T p.S238= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as rs757773066, COSV100618699, COSV58547218; called by muse, mutect2, varscan2
- CACNA1C | c.1217+303G>C | Intron (SNP) | VAF 23/133 reads (17%) | catalogued as COSV100221382, COSV59754368; called by muse, mutect2, varscan2
- MED25 | c.-2G>T | 5'UTR (SNP) | VAF 13/25 reads (52%) | catalogued as COSV100457832; called by mutect2, varscan2
